CCDI case PBCHMS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a0ee0c93-0e51-4e35-a0d1-2f87efe7fd5a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 17.6 years (6,417 days).

Biospecimens (3 samples)
- Sample 0DSEKI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSEKU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSEL8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
